TARGET case TARGET-30-PAMANU — Neuroblastoma (TARGET-NBL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neuroepitheliomatous Neoplasms; Primary site: Peripheral nerves and autonomic nervous system. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/95079033-5e52-5bb2-8f71-1cdb9da744e3

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 3 years; Vital status: Alive.

Diagnoses (1)
1. Neuroblastoma, NOS: ICD-O-3 morphology code: 9500/3; ICD-10 code: C47.0; Tissue or organ of origin: Peripheral nerves and autonomic nervous system of head, face, and neck; Classification of tumor: primary; Age at diagnosis: 3.8 years (1,398 days); Year of diagnosis: 2002; Days to last follow up: 3,571 days (9.8 years); Cog neuroblastoma risk group: High Risk; Inpc grade: Undifferentiated or Poorly Differentiated; INSS stage: Stage 4; Mitosis karyorrhexis index: Low.
   Treatment given: Protocol identifier: ANBL00B1.

Follow-up (1 entry)
- Days to follow up: 3,571 days (9.8 years); Event-free: no event (relapse, second malignancy or death) recorded through day 3,571; Year of follow up: 2012.

Molecular and laboratory tests
- Test: Abnormal, NOS; Ploidy: Hyperdiploid.

Biospecimens (2 samples)
- Sample TARGET-30-PAMANU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
- Sample TARGET-30-PAMANU-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_NBL_ClinicalData_Discovery_20230523.xlsx (sheet Clinical Data):
- First Event: Censored
- Overall Survival Time in Days: 3571
- Ploidy: Hyperdiploid (DI>1)
- Ploidy Value: 1.44
- Histology: Unfavorable
- MKI: Low
- ICDO Description: Peripheral nerves and Autonomic nervous system of head, face, and neck (excludes Peripheral nerves and Autonomic nervous system of Orbit C69.6) Peripheral nerves and Autonomic nervous system of (see list under C47): . Cheek . Chin . Face . Forehead .
